Somatic mutation profile of tumor specimen TCGA-NC-A5HH-01A (aliquot TCGA-NC-A5HH-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HH, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 53.3 years (19,485 days).
Specimen TCGA-NC-A5HH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12cf8610-1cae-41ba-8f55-19bfb8132e0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HH-10A (Blood Derived Normal), aliquot TCGA-NC-A5HH-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6a539e9-6d2c-4406-ae09-98c466e8d61f

The open-access MAF lists 382 somatic variants for this specimen: 291 protein-altering or splice-affecting, 86 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 254, Silent 86, Nonsense Mutation 17, Splice Site 7, Frame Shift Del 7, Splice Region 4, Intron 2, RNA 2, 3'UTR 1, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 120/137 reads (88%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs121913474, COSV60638681, COSV60642677; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 200/341 reads (59%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCC2 | c.3531G>T p.E1177D | Missense Mutation (SNP) | VAF 73/91 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV100966404; called by muse, mutect2, varscan2
- ACAD11 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs770146394, COSV99391645; called by muse, mutect2, varscan2
- ACSM5 | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV100088497; called by muse, mutect2, varscan2
- ACSS3 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54097999, COSV99698373; called by muse, mutect2, varscan2
- AEBP1 | c.836C>G p.P279R | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs752164012, COSV99788479; called by muse, varscan2
- AFG1L | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100933867; called by muse, mutect2, varscan2
- AGAP6 | c.472G>T p.D158Y (on ENST00000374056 / NM_001365867.1; = p.D181Y on NM_001077665.2) | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV100929045; called by muse, mutect2, varscan2
- AGTR1 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100836947; called by muse, mutect2, varscan2
- AKIRIN1 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 71/98 reads (72%) | catalogued as COSV100881974; called by muse, mutect2, varscan2
- AMER3 | c.1948G>C p.V650L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1345230399, COSV100366047; called by muse, mutect2, varscan2
- AMPH | c.854C>A p.S285Y | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100341065; called by muse, mutect2, varscan2
- ANK2 | c.3496C>A p.P1166T | Missense Mutation (SNP) | VAF 75/102 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000019; called by muse, mutect2, varscan2
- ANKRD11 | c.3089A>G p.E1030G | Missense Mutation (SNP) | VAF 83/108 reads (77%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99968458; called by muse, mutect2, varscan2
- ANKRD11 | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99968459; called by muse, mutect2
- AOC3 | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99519985; called by muse, mutect2, varscan2
- AOX1 | c.1234G>T p.V412F | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV101021783; called by muse, mutect2, varscan2
- APCS | c.131C>A p.P44Q | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138308518, COSV54817850; called by muse, mutect2, varscan2
- APOA1 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT tolerated (0.13); PolyPhen benign (0.199); catalogued as COSV99369146; called by muse, mutect2, varscan2
- ARFGEF3 | c.5385G>C p.K1795N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV99292495; called by muse, mutect2, varscan2
- ARID1A | c.3968G>T p.R1323L | Missense Mutation (SNP) | VAF 72/101 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775802127, COSV100250496, COSV61392370; called by muse, varscan2
- ARID4A | c.3739C>T p.P1247S | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV100794055; called by muse, mutect2
- ARNT | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs587624534, COSV100590992, COSV100591109; called by muse, mutect2, varscan2
- ASXL3 | c.4229A>T p.H1410L | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV52481379, COSV99036115; called by muse, mutect2, varscan2
- ATG13 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV100365531; called by muse, mutect2, varscan2
- ATP13A2 | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100453947; called by muse, mutect2, varscan2
- ATP1A2 | c.2357C>G p.P786R | Missense Mutation (SNP) | VAF 89/152 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1209724722, CM075992, COSV100767659; called by muse, mutect2, varscan2
- BIRC6 | c.5772A>G p.I1924M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV101427924; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4292T>A p.L1431Q | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100863605; called by muse, mutect2, varscan2
- BNC2 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101032300; called by muse, mutect2, varscan2
- C8B | c.1369C>A p.Q457K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV100980706; called by muse, mutect2, varscan2
- CACNA1E | c.6068C>A p.T2023N (on ENST00000367573 / NM_001205293.3; = p.T1980N on NM_000721.4) | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100701356; called by muse, mutect2, varscan2
- CACTIN | c.2137G>T p.G713W | Missense Mutation (SNP) | VAF 136/195 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698316; called by muse, mutect2, varscan2
- CAPSL | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as rs868067758, COSV101274181; called by muse, mutect2, varscan2
- CATSPERB | c.3218T>C p.F1073S | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99830884; called by muse, mutect2, varscan2
- CBARP | c.430+7G>T | Splice Region (SNP) | VAF 19/33 reads (58%) | catalogued as COSV99289386; called by muse, mutect2, varscan2
- CBLN4 | c.221C>A p.S74* | Nonsense Mutation (SNP) | VAF 154/351 reads (44%) | catalogued as COSV50352360, COSV99290383; called by muse, mutect2, varscan2
- CC2D1A | c.820G>C p.A274P | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100528288; called by muse, varscan2
- CCDC39 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.895); catalogued as rs760987849, COSV99867453; called by muse, varscan2
- CCSER1 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated (0.57); PolyPhen benign (0.049); catalogued as COSV100388421; called by muse, mutect2, varscan2
- CDH10 | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100050270; called by muse, mutect2, varscan2
- CDH23 | c.6313G>T p.V2105F | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV99819158; called by muse, mutect2, varscan2
- CDH6 | c.2366A>G p.D789G | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV99418209; called by muse, mutect2, varscan2
- CEACAM3 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.45); catalogued as rs368017478; called by muse, mutect2, varscan2
- CENPW | c.188G>T p.C63F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs746698752, COSV100851374, COSV64177147; called by muse, mutect2, varscan2
- CEP152 | c.5042C>T p.S1681L (on ENST00000380950 / NM_001194998.2; = p.S1625L on NM_014985.4) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as COSV100358553; called by muse, mutect2
- CHAMP1 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 187/250 reads (75%) | SIFT tolerated (0.18); PolyPhen benign (0.154); catalogued as rs1176176958, COSV63521653; called by muse, mutect2, varscan2
- CLEC1A | c.761G>C p.R254P | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.436); catalogued as COSV100191187, COSV59531017; called by muse, mutect2, varscan2
- CLTC | c.1763A>C p.N588T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99291786, COSV99292056; called by muse, mutect2, varscan2
- CNBD1 | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV101575275; called by muse, mutect2, varscan2
- CNTN3 | c.1929G>T p.W643C | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99723426; called by muse, mutect2, varscan2
- COL20A1 | c.1591G>T p.D531Y | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100489995; called by muse, mutect2, varscan2
- COL22A1 | c.2467G>T p.E823* | Nonsense Mutation (SNP) | VAF 47/76 reads (62%) | catalogued as COSV57329317; called by muse, mutect2, varscan2
- COL28A1 | c.1975G>A p.G659R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV101258336; called by muse, mutect2, varscan2
- COPS7A | c.328-1G>T p.X110_splice | Splice Site (SNP) | VAF 77/146 reads (53%) | catalogued as COSV99976397; called by muse, mutect2, varscan2
- CORIN | c.1186A>G p.T396A | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99903024; called by muse, mutect2, varscan2
- CRX | c.590C>G p.P197R | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as COSV55759348, COSV99704366; called by muse, mutect2, varscan2
- CSPG4 | c.2398G>T p.E800* | Nonsense Mutation (SNP) | VAF 27/102 reads (26%) | catalogued as COSV100413494; called by muse, mutect2, varscan2
- CXorf58 | c.610T>A p.W204R | Missense Mutation (SNP) | VAF 183/205 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101002937; called by muse, mutect2, varscan2
- DCDC1 | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100662802; called by muse, mutect2, varscan2
- DDX31 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.61); PolyPhen benign (0.136); catalogued as COSV100139921; called by muse, mutect2, varscan2
- DEPDC5 | c.2680A>G p.R894G (on ENST00000400246; = p.R963G on NM_014662.5) | Missense Mutation (SNP) | VAF 70/86 reads (81%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs771624840, COSV99834515; called by muse, mutect2, varscan2
- DLX5 | c.32G>T p.S11I | Missense Mutation (SNP) | VAF 93/129 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV99756246, COSV99756626; called by muse, mutect2, varscan2
- DMRT2 | c.602G>C p.S201T | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as rs778425270, COSV99425938; called by muse, mutect2, varscan2
- DNAH5 | c.6217A>G p.M2073V | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs752077073, COSV99445689; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJB8 | c.401T>A p.F134Y | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as COSV100048129; called by muse, mutect2, varscan2
- DNAJB8 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV100048131; called by muse, mutect2, varscan2
- DNAJC5 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.245); catalogued as rs1006274437, COSV100694154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAL1 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100225731; called by muse, mutect2, varscan2
- DOCK8 | c.5188G>T p.G1730C | Missense Mutation (SNP) | VAF 73/89 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV101209812; called by muse, mutect2, varscan2
- DYRK2 | c.908T>A p.L303Q (on ENST00000344096 / NM_006482.3; = p.L230Q on NM_003583.4) | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165202; called by muse, mutect2, varscan2
- EHBP1L1 | c.1966A>T p.T656S | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100499695; called by muse, mutect2, varscan2
- EIF3L | c.1656G>C p.E552D | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.039); catalogued as rs1196481919, COSV101094461; called by muse, mutect2, varscan2
- ELAVL1 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 53/66 reads (80%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs770736507, COSV100688178; called by muse, mutect2, varscan2
- ELOA3C | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 50/1262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747137882, COSV99796041; called by muse, mutect2
- ENTPD2 | c.1287C>T p.A429= (on ENST00000355097 / NM_203468.3; = p.A406= on NM_001246.4) | Splice Region (SNP) | VAF 10/12 reads (83%) | catalogued as rs768417706, COSV100445653; called by muse, varscan2
- EPB42 | c.862G>T p.V288L (on ENST00000441366 / NM_001114134.2; = p.V318L on NM_000119.3) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as COSV100281810, COSV55749292; called by muse, mutect2, varscan2
- EPHB1 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV101212743, COSV67654461; called by muse, mutect2, varscan2
- EVPL | c.3853G>T p.G1285W | Missense Mutation (SNP) | VAF 121/155 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100044042, COSV56915290; called by muse, mutect2, varscan2
- EXO1 | c.1041G>T p.M347I | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100799631; called by muse, mutect2, varscan2
- EYS | c.683G>T p.C228F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV100675772; called by muse, mutect2
- F11 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 97/144 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs775585859, COSV53002350; called by muse, mutect2, varscan2
- FAT3 | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53177656; called by muse, mutect2, varscan2
- FGD4 | c.2252C>T p.P751L | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99846809; called by muse, mutect2, varscan2
- FLG | c.5440C>A p.R1814S | Missense Mutation (SNP) | VAF 381/1012 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.211); catalogued as COSV100910509, COSV100910637; called by muse, mutect2, varscan2
- FLG2 | c.3496T>C p.C1166R | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV101165617; called by muse, mutect2, varscan2
- FLI1 | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470685669, COSV55647961; called by mutect2, varscan2
- FOXO4 | c.1000G>C p.V334L | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100446788; called by muse, mutect2, varscan2
- FRMD3 | c.684G>T p.K228N | Missense Mutation (SNP) | VAF 125/182 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100418289; called by muse, mutect2, varscan2
- FRRS1 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99789703; called by muse, mutect2, varscan2
- FRYL | c.8608G>A p.E2870K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs778278290, COSV99975976; called by muse, mutect2, varscan2
- GAA | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 41/56 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as CX071473, COSV100162966; called by muse, mutect2, varscan2
- GALNT18 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs374870394, COSV57157382; called by muse, varscan2
- GDF7 | c.908C>A p.P303Q | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99693985; called by muse, mutect2, varscan2
- GHR | c.549T>G p.I183M | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as COSV100049965; called by muse, mutect2, varscan2
- GPLD1 | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100015067, COSV57761601; called by muse, mutect2, varscan2
- GRHL1 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs755273704, COSV61406777; called by muse, mutect2, varscan2
- GRIN2B | c.923T>A p.L308Q | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); catalogued as COSV101662933; called by muse, mutect2, varscan2
- GRK1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as rs767946791, COSV100175265; called by muse, varscan2
- HEY1 | c.667C>A p.H223N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.201); catalogued as COSV100559167; called by muse, mutect2, varscan2
- HIVEP1 | c.2826A>T p.Q942H | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.694); catalogued as COSV101044775; called by muse, mutect2, varscan2
- HNF4A | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV100291124; called by muse, mutect2, varscan2
- HOOK1 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 48/62 reads (77%) | catalogued as rs1478330334, COSV64618654; called by muse, mutect2, varscan2
- HTR1A | c.1202C>G p.A401G | Missense Mutation (SNP) | VAF 213/305 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100108947; called by muse, mutect2, varscan2
- IL1RAP | c.526A>C p.T176P | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV99299095; called by muse, mutect2
- INSRR | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100947202; called by muse, mutect2, varscan2
- ITLN1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 105/235 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100406136; called by muse, mutect2, varscan2
- KCNA4 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as rs757484309, COSV100068606; called by muse, mutect2, varscan2
- KCNA7 | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as rs757480933, COSV99671832, COSV99671956; called by muse, mutect2, varscan2
- KCNC1 | c.311G>T p.C104F | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99788818; called by muse, mutect2, varscan2
- KCNC2 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV100128298, COSV54364383; called by muse, mutect2, varscan2
- KCNH1 | c.559-2A>T p.X187_splice | Splice Site (SNP) | VAF 39/90 reads (43%) | catalogued as COSV99657569; called by muse, mutect2, varscan2
- KCNJ16 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV99387914; called by muse, mutect2, varscan2
- KCNK17 | c.215C>A p.P72Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs754336373, COSV100949091, COSV64678701; called by muse, varscan2
- KIAA1549L | c.656C>T p.S219F (on ENST00000321505; = p.S516F on NM_012194.3) | Missense Mutation (SNP) | VAF 92/217 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs894288286, COSV99682727; called by muse, mutect2, varscan2
- KMT2D | c.12694C>T p.Q4232* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99978089; called by muse, mutect2, varscan2
- KNG1 | c.1159C>A p.P387T | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99405174; called by muse, mutect2, varscan2
- KSR2 | c.1304G>A p.G435D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100194286; called by muse, mutect2, varscan2
- LAMA1 | c.841T>C p.W281R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV101055227; called by muse, mutect2, varscan2
- LARP1B | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV99217830; called by muse, mutect2, varscan2
- LCE1E | c.52C>G p.P18A | Missense Mutation (SNP) | VAF 104/264 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as rs774139045, COSV100908513; called by muse, mutect2, varscan2
- LCMT2 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99979923; called by muse, mutect2, varscan2
- LIFR | c.1784A>C p.E595A | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99663378; called by muse, mutect2, varscan2
- LPCAT1 | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52039577; called by muse, mutect2
- LRFN5 | c.1400C>A p.T467K | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.489); catalogued as COSV99982664; called by muse, mutect2, varscan2
- LRFN5 | c.1658A>G p.K553R | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT tolerated (0.26); PolyPhen benign (0.105); catalogued as COSV99982665; called by muse, mutect2, varscan2
- LRP1 | c.6617G>A p.R2206H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1371377915, COSV54503511, COSV54514106; called by muse, mutect2, varscan2
- LRP1B | c.9395C>A p.P3132H | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101253427; called by muse, mutect2, varscan2
- LRP1B | c.3296C>G p.T1099S | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.952); catalogued as COSV101253428, COSV101262512; called by muse, mutect2, varscan2
- LRRCC1 | c.1125T>C p.S375= | Splice Region (SNP) | VAF 11/75 reads (15%) | catalogued as rs1173799727, COSV100835303; called by muse, mutect2, varscan2
- LRRK2 | c.4639G>T p.V1547L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100109387; called by muse, mutect2, varscan2
- MAGEB2 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1489667572, COSV100975581; called by muse, mutect2, varscan2
- MAN2A1 | c.1008G>T p.W336C | Missense Mutation (SNP) | VAF 50/72 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99810528; called by muse, mutect2, varscan2
- MAP1S | c.2413G>T p.G805C | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100140854; called by muse, varscan2
- MAST3 | c.776G>T p.S259I | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV99444551; called by muse, mutect2, varscan2
- MCAM | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV99875599; called by muse, mutect2, varscan2
- MIP | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57510924; called by muse, mutect2, varscan2
- MTA3 | c.319G>T p.G107* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100608740; called by muse, mutect2, varscan2
- MUC13 | c.1031G>A p.C344Y | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100222241; called by muse, mutect2, varscan2
- MUC16 | c.20450C>T p.S6817F | Missense Mutation (SNP) | VAF 51/80 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.935); catalogued as COSV67446290; called by muse, mutect2, varscan2
- MYO16 | c.2256G>C p.L752F | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99193581; called by muse, mutect2, varscan2
- MYO1B | c.2834G>T p.S945I (on ENST00000304164; = p.S887I on NM_012223.5) | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100268724; called by muse, mutect2, varscan2
- MYO1F | c.3118C>T p.R1040W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs781530064, COSV100596415; called by muse, mutect2, varscan2
- MYOF | c.5566C>A p.P1856T | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100825293, COSV63712513; called by muse, mutect2, varscan2
- MYOF | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 59/83 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825295, COSV100826106; called by muse, mutect2, varscan2
- NCAN | c.2373T>A p.D791E | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as COSV99386634; called by muse, mutect2, varscan2
- NCAPD3 | c.2980A>T p.I994F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1390680207, COSV101598325; called by muse, mutect2, varscan2
- NEDD4L | c.2487G>T p.E829D (on ENST00000400345 / NM_001144967.3; = p.E809D on NM_015277.6) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.317); catalogued as COSV99893610; called by muse, mutect2, varscan2
- NFS1 | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs375982656; called by muse, mutect2, varscan2
- NGB | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99836208; called by muse, mutect2, varscan2
- NIPBL | c.6826A>T p.S2276C | Missense Mutation (SNP) | VAF 91/289 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99239073; called by muse, mutect2, varscan2
- NIPSNAP1 | c.217A>C p.K73Q | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV99331045; called by muse, mutect2, varscan2
- NKD2 | c.786T>C p.P262= | Splice Region (SNP) | VAF 31/155 reads (20%) | catalogued as rs1167248076, COSV99723827; called by muse, mutect2, varscan2
- NMD3 | c.1073A>T p.Q358L | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1289973297, COSV100664615; called by muse, mutect2, varscan2
- NMUR2 | c.481C>G p.R161G | Missense Mutation (SNP) | VAF 53/75 reads (71%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV99676648, COSV99676784; called by muse, mutect2, varscan2
- NOP2 | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV100444694; called by muse, mutect2, varscan2
- NTRK3 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV62314509, COSV62319709; called by muse, mutect2, varscan2
- NUP160 | c.1210A>T p.T404S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as COSV101021334; called by muse, mutect2, varscan2
- OCA2 | c.1289G>C p.C430S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100667015; called by muse, mutect2, varscan2
- OR13C3 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 97/160 reads (61%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV101053267; called by muse, mutect2, varscan2
- OR2A25 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 123/165 reads (75%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101376345; called by muse, mutect2, varscan2
- OR2J3 | c.392G>T p.R131I | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV65849682; called by muse, mutect2, varscan2
- OR4P4 | c.690A>T p.R230S | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100111578; called by muse, mutect2, varscan2
- OR52E4 | c.759C>A p.Y253* | Nonsense Mutation (SNP) | VAF 54/83 reads (65%) | catalogued as COSV100389157; called by muse, mutect2, varscan2
- OR52E6 | c.127G>C p.G43R | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV100259128; called by muse, mutect2, varscan2
- OR52N5 | c.656A>G p.D219G | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100399602; called by muse, mutect2, varscan2
- OR5B2 | c.468C>A p.F156L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs200888315, COSV100222789, COSV100223030; called by muse, mutect2, varscan2
- OR5D14 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV100162178; called by muse, mutect2, varscan2
- OR5J2 | c.101T>G p.I34S | Missense Mutation (SNP) | VAF 96/215 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100398915; called by muse, mutect2, varscan2
- OR6S1 | c.361T>A p.S121T | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV100289291; called by muse, mutect2, varscan2
- OR8K3 | c.939A>C p.*313Yext*10 (on ENST00000641662; = p.*313Yext*? on NM_001005202.1) | Nonstop Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100449678, COSV57131983; called by muse, mutect2, varscan2
- P3H2 | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV100077113; called by muse, mutect2, varscan2
- PAPPA2 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 161/221 reads (73%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV62780981; called by muse, mutect2, varscan2
- PARP10 | c.820A>T p.K274* | Nonsense Mutation (SNP) | VAF 71/147 reads (48%) | catalogued as COSV100477758; called by muse, mutect2, varscan2
- PARP8 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.952); catalogued as COSV99890175; called by muse, mutect2, varscan2
- PCDH11X | c.3846G>A p.W1282* | Nonsense Mutation (SNP) | VAF 89/132 reads (67%) | catalogued as COSV100008854; called by muse, mutect2, varscan2
- PCDHGA4 | c.1535G>C p.S512T | Missense Mutation (SNP) | VAF 117/161 reads (73%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99532040, COSV99534996; called by muse, mutect2, varscan2
- PCDHGB3 | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT tolerated (0.33); PolyPhen benign (0.074); catalogued as COSV99532047; called by muse, mutect2, varscan2
- PCDHGB3 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53998728; called by muse, mutect2, varscan2
- PCMTD2 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as COSV100204032; called by muse, mutect2, varscan2
- PDE5A | c.1556A>C p.Q519P | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99308348; called by muse, mutect2, varscan2
- PDGFRA | c.1067T>G p.L356R | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57275766, COSV99955614; called by muse, mutect2, varscan2
- PDILT | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 64/76 reads (84%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV100199101, COSV56703954; called by muse, mutect2, varscan2
- PDZD2 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as COSV99223907; called by muse, mutect2
- PEAK1 | c.5028G>C p.Q1676H | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100432532; called by muse, mutect2, varscan2
- PEAK1 | c.3508A>G p.K1170E | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as COSV100432535; called by muse, mutect2, varscan2
- PER2 | c.915G>C p.E305D | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99611494; called by muse, mutect2, varscan2
- PGR | c.1907-2A>G p.X636_splice | Splice Site (SNP) | VAF 15/18 reads (83%) | catalogued as COSV99677543; called by muse, varscan2
- PID1 | c.260C>G p.T87S (on ENST00000354069 / NM_001330156.1; = p.T85S on NM_017933.5) | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV100819554, COSV62476137; called by muse, mutect2, varscan2
- PLEKHG2 | c.1114C>G p.R372G | Missense Mutation (SNP) | VAF 101/485 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs774367341, COSV99216934, COSV99217429; called by muse, mutect2, varscan2
- PLPP2 | c.637A>T p.T213S | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV99514483; called by muse, mutect2, varscan2
- PNLIP | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 88/105 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65040446; called by muse, mutect2, varscan2
- PNPT1 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99569671; called by muse, mutect2, varscan2
- POLQ | c.5008A>T p.R1670* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99951711; called by muse, mutect2, varscan2
- POLQ | c.3382C>G p.L1128V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV99951712; called by muse, mutect2, varscan2
- PRAMEF1 | c.50T>G p.L17R | Missense Mutation (SNP) | VAF 110/310 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100179465; called by muse, mutect2, varscan2
- PRAMEF4 | c.632A>T p.E211V | Missense Mutation (SNP) | VAF 156/307 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99339530; called by muse, mutect2, varscan2
- PRDM14 | c.365C>A p.A122E | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.007); catalogued as COSV52573470, COSV99399912; called by muse, mutect2, varscan2
- PRDM16 | c.3145G>T p.G1049W | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99575160; called by muse, mutect2, varscan2
- PRNP | c.47G>C p.W16S | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV101057199; called by muse, mutect2, varscan2
- PROKR1 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV100375299; called by muse, mutect2, varscan2
- PSG8 | c.188C>A p.T63N | Missense Mutation (SNP) | VAF 153/221 reads (69%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100126009; called by muse, mutect2, varscan2
- PTPRH | c.1439G>T p.S480I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.8); catalogued as COSV99670742; called by muse, mutect2, varscan2
- PTPRT | c.1483G>T p.G495W | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.939); catalogued as COSV100625556, COSV61967919, COSV62000653; called by muse, mutect2, varscan2
- QSER1 | c.3402G>T p.K1134N (on ENST00000399302; = p.K1263N on NM_001076786.3) | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101234670, COSV67901853; called by muse, mutect2, varscan2
- R3HDM2 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 26/98 reads (27%) | catalogued as COSV100714975; called by muse, varscan2
- RBSN | c.1726G>T p.G576C | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); catalogued as COSV99515048; called by muse, mutect2, varscan2
- RDH8 | c.830C>A p.T277N (on ENST00000651512; = p.T257N on NM_015725.4) | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50674522; called by muse, mutect2, varscan2
- RGS22 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.236); catalogued as COSV100693014; called by muse, mutect2, varscan2
- RIT2 | c.102C>A p.S34R | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99949700, COSV99951040; called by muse, mutect2, varscan2
- RPS6KB2 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100396272; called by muse, mutect2, varscan2
- RTTN | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs1399849740, COSV99731254; called by muse, mutect2, varscan2
- SCAF8 | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65793111; called by muse, mutect2, varscan2
- SCN1A | c.4403T>C p.I1468T (on ENST00000303395 / NM_001202435.3; = p.I1457T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100319487; called by muse, mutect2, varscan2
- SELENOI | c.1023C>G p.Y341* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as COSV99564236; called by mutect2, varscan2
- SEMG2 | c.1475G>T p.S492I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV101033973; called by muse, mutect2, varscan2
- SGPP2 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV100346130; called by muse, mutect2, varscan2
- SIRPD | c.220T>G p.L74V | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV101064855; called by muse, mutect2, varscan2
- SLAMF6 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100924836; called by muse, mutect2, varscan2
- SLC17A3 | c.374G>T p.C125F | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (0.44); PolyPhen benign (0.115); catalogued as COSV100399089, COSV57761235; called by muse, mutect2, varscan2
- SLC17A8 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0.054); catalogued as COSV100035238; called by muse, mutect2, varscan2
- SLC26A2 | c.656T>G p.I219S | Missense Mutation (SNP) | VAF 83/101 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99640005; called by muse, mutect2, varscan2
- SLC28A1 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV99722644; called by muse, mutect2, varscan2
- SLC30A10 | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 86/256 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV100751436; called by muse, mutect2, varscan2
- SLC39A12 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 85/121 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV101069864; called by muse, mutect2, varscan2
- SLC4A1 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398477044, CM971386, COSV52258410, COSV52264172; called by muse, mutect2, varscan2
- SLC5A12 | c.1476-1G>T p.X492_splice | Splice Site (SNP) | VAF 35/92 reads (38%) | catalogued as COSV101237589, COSV101237724; called by muse, mutect2, varscan2
- SLC6A17 | c.17A>T p.K6I | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100521109; called by muse, mutect2, varscan2
- SLC6A19 | c.664-2A>T p.X222_splice | Splice Site (SNP) | VAF 16/213 reads (8%) | catalogued as COSV100443268; called by muse, mutect2
- SLCO4C1 | c.1912A>G p.I638V | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs1489521591, COSV100194568; called by muse, mutect2, varscan2
- SLITRK1 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100999806; called by muse, mutect2, varscan2
- SLTM | c.2380G>T p.D794Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100998569; called by muse, mutect2, varscan2
- SNX1 | c.1373C>G p.S458C | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99975942; called by muse, mutect2, varscan2
- SP1 | c.1770T>A p.D590E (on ENST00000327443 / NM_138473.3; = p.D583E on NM_003109.1) | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.118); catalogued as COSV100540435; called by muse, mutect2, varscan2
- SPATA31D1 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100782524; called by muse, mutect2, varscan2
- SPEF2 | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV56795562, COSV99213751; called by muse, mutect2, varscan2
- SPSB4 | c.651G>T p.W217C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100141055; called by muse, mutect2, varscan2
- SPTLC1 | c.10G>C p.A4P | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.037); catalogued as COSV99364552; called by muse, mutect2, varscan2
- SRR | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.42); catalogued as COSV100026863; called by muse, mutect2, varscan2
- SSTR5 | c.983A>C p.K328T | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV99559538; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1046A>T p.Q349L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | PolyPhen benign (0.285); catalogued as COSV99030621, COSV99336260; called by muse, mutect2, varscan2
- ST8SIA5 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 27/65 reads (42%) | PolyPhen probably damaging (1); catalogued as COSV100164518; called by muse, mutect2, varscan2
- STAR | c.683A>T p.H228L | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99378915; called by muse, mutect2, varscan2
- STRC | c.4886C>A p.S1629Y | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100294448, COSV55852094, COSV55852250; called by muse, mutect2, varscan2
- TAAR1 | c.998T>A p.L333* | Nonsense Mutation (SNP) | VAF 10/11 reads (91%) | catalogued as COSV99257475; called by muse, mutect2, varscan2
- TBX15 | c.1647C>A p.N549K (on ENST00000369429 / NM_001330677.2; = p.N443K on NM_152380.3) | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.14); catalogued as COSV52874650, COSV99253681; called by muse, mutect2, varscan2
- TIMELESS | c.1510G>T p.E504* | Nonsense Mutation (SNP) | VAF 28/99 reads (28%) | catalogued as COSV99973702; called by muse, mutect2, varscan2
- TLR10 | c.469T>C p.S157P | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1351998254, COSV100457461; called by muse, mutect2, varscan2
- TMC2 | c.1679C>A p.P560H | Missense Mutation (SNP) | VAF 71/123 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100727381; called by muse, mutect2, varscan2
- TNFRSF25 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.174); catalogued as rs1296166147; called by muse, mutect2
- TOP1 | c.1921G>C p.E641Q | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV100793693; called by muse, mutect2, varscan2
- TRIM45 | c.251G>C p.R84P | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99868259; called by muse, mutect2, varscan2
- TRIM46 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.109); catalogued as COSV100103921; called by muse, mutect2, varscan2
- TRPM7 | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0.01); catalogued as COSV100539443, COSV57919629; called by muse, mutect2, varscan2
- TSPAN7 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT tolerated (0.12); PolyPhen benign (0.152); catalogued as COSV99730343; called by muse, mutect2, varscan2
- TSPY1 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as COSV101369642; called by muse, mutect2, varscan2
- TTI1 | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 64/109 reads (59%) | catalogued as COSV100989584, COSV65062027; called by muse, mutect2, varscan2
- TTN | c.68105C>A p.A22702D (on ENST00000591111; = p.A15278D on NM_003319.4) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | PolyPhen possibly damaging (0.626); catalogued as COSV100596887; called by muse, mutect2, varscan2
- TTN | c.24442G>T p.V8148L (on ENST00000591111; = p.V7221L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/34 reads (65%) | PolyPhen benign (0); catalogued as COSV100596894; called by muse, mutect2, varscan2
- TYR | c.805T>C p.F269L | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54470967, COSV99633214; called by muse, mutect2, varscan2
- UBASH3A | c.1141A>G p.R381G | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.058); catalogued as COSV99369291; called by muse, mutect2, varscan2
- USH2A | c.11372T>C p.V3791A | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs758024950, COSV100229909; called by muse, mutect2, varscan2
- USP16 | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100537810; called by muse, mutect2, varscan2
- USP9X | c.2854C>A p.Q952K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as rs1394335521, COSV100198559; called by muse, mutect2, varscan2
- VPS39 | c.929C>T p.P310L (on ENST00000348544 / NM_001301138.2; = p.P299L on NM_015289.5) | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100529006; called by muse, mutect2, varscan2
- VWA3A | c.2741G>T p.R914I | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100240658; called by muse, mutect2, varscan2
- VWCE | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 236/555 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100075637; called by muse, mutect2, varscan2
- WASF1 | c.500A>C p.Q167P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99661071; called by muse, mutect2, varscan2
- WDFY3 | c.6387G>T p.L2129F | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99882126; called by muse, mutect2, varscan2
- WDR70 | c.1595C>T p.T532I | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99457748; called by muse, mutect2
- ZFP64 | c.1900G>A p.G634R | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99402006; called by muse, mutect2, varscan2
- ZMAT5 | c.390A>T p.E130D | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99334695; called by muse, mutect2, varscan2
- ZNF343 | c.177+1G>T p.X59_splice | Splice Site (SNP) | VAF 28/64 reads (44%) | catalogued as rs560550921, COSV99601239; called by muse, mutect2, varscan2
- ZNF474 | c.394A>T p.R132W | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561444668, COSV99682025; called by muse, mutect2, varscan2
- ZNF628 | c.1899G>T p.M633I | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV99219812; called by muse, mutect2, varscan2
- ZNF649 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 74/100 reads (74%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV100030815, COSV56817984; called by muse, mutect2, varscan2
- ZNF827 | c.2347A>C p.S783R | Missense Mutation (SNP) | VAF 69/105 reads (66%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as COSV101061194; called by muse, mutect2, varscan2
- ZRANB1 | c.851A>T p.Y284F | Missense Mutation (SNP) | VAF 97/115 reads (84%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV100669053; called by muse, mutect2, varscan2
- ZSCAN1 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99991394; called by muse, mutect2, varscan2
- ZSWIM2 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV99719956; called by muse, mutect2, varscan2
- ZZEF1 | c.3152A>G p.H1051R | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1442251697, COSV101067551; called by muse, mutect2, varscan2
- ARHGAP17 | c.2629del p.E877Rfs*65 (on ENST00000289968 / NM_001006634.3; = p.E799Rfs*65 on NM_018054.6) | Frame Shift Del (DEL) | VAF 100/176 reads (57%) | called by mutect2, pindel, varscan2
- ATP13A5 | c.1086del p.P363Lfs*18 | Frame Shift Del (DEL) | VAF 28/170 reads (16%) | called by mutect2, pindel, varscan2
- CD40 | c.420dup p.T141Yfs*28 | Frame Shift Ins (INS) | VAF 84/189 reads (44%) | called by mutect2, pindel, varscan2
- CKAP5 | c.3556del p.T1186Lfs*11 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel
- CLEC4F | c.1613_1614del p.W538Sfs*51 | Frame Shift Del (DEL) | VAF 38/190 reads (20%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 155/199 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MCPH1 | c.2247del p.P750Rfs*29 | Frame Shift Del (DEL) | VAF 35/69 reads (51%) | called by mutect2, pindel, varscan2
- NOD2 | c.1619_1632del p.L540Pfs*34 | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | called by pindel, varscan2
- TUBGCP3 | c.1881+1del p.X627_splice | Splice Site (DEL) | VAF 27/109 reads (25%) | called by mutect2, pindel, varscan2
- ABCG1 | c.543G>T p.S181= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as COSV100493889, COSV59206098; called by muse, mutect2, varscan2
- ADGRB3 | c.3357C>A p.A1119= | Silent (SNP) | VAF 52/188 reads (28%) | catalogued as COSV53238842, COSV99483836; called by muse, mutect2, varscan2
- AGTR1 | c.120G>A p.V40= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as rs767852386, COSV100836946; called by muse, mutect2, varscan2
- AHNAK | c.2343C>T p.S781= | Silent (SNP) | VAF 45/291 reads (15%) | catalogued as rs114762806, COSV57210217; called by muse, mutect2, varscan2
- AKAP4 | c.606G>A p.Q202= | Silent (SNP) | VAF 145/173 reads (84%) | catalogued as COSV62073944, COSV62074900; called by muse, mutect2, varscan2
- ALDH1L1 | c.1032C>T p.S344= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99856551; called by muse, mutect2, varscan2
- ANO5 | c.1566C>T p.N522= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV61083178, COSV61087332; called by muse, mutect2, varscan2
- AOC1 | c.1338G>A p.K446= | Silent (SNP) | VAF 48/63 reads (76%) | catalogued as rs1470311581, COSV100710631; called by muse, mutect2, varscan2
- AQP9 | c.804C>A p.I268= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV99582668; called by muse, mutect2, varscan2
- ARPP21 | c.426G>T p.T142= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99491182, COSV99492673; called by muse, mutect2, varscan2
- ATP11C | c.2928G>T p.G976= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as COSV100557489, COSV59564210; called by muse, mutect2, varscan2
- BAZ1B | c.1308G>A p.K436= | Silent (SNP) | VAF 46/70 reads (66%) | catalogued as rs1554573163, COSV100289611; called by muse, mutect2, varscan2
- C4orf51 | c.141A>C p.T47= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV101439981, COSV71263755; called by muse, mutect2, varscan2
- CFAP61 | c.1023G>T p.P341= | Silent (SNP) | VAF 61/119 reads (51%) | catalogued as COSV99843527; called by muse, mutect2, varscan2
- CKAP5 | c.5313A>G p.K1771= (on ENST00000529230 / NM_001008938.4; = p.K1711= on NM_014756.3) | Silent (SNP) | VAF 69/174 reads (40%) | catalogued as COSV56368320; called by muse, mutect2, varscan2
- CLIP1 | c.717G>T p.G239= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100211285; called by muse, mutect2, varscan2
- CRISP2 | c.711A>G p.L237= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV100188905; called by muse, mutect2, varscan2
- DMBT1 | c.5352C>A p.V1784= (on ENST00000338354 / NM_001377530.1; = p.V1027= on NM_004406.3) | Silent (SNP) | VAF 414/539 reads (77%) | catalogued as COSV100352254, COSV57561742; called by muse, mutect2, varscan2
- DNAH5 | c.1296A>T p.I432= | Silent (SNP) | VAF 79/109 reads (72%) | catalogued as COSV99445693; called by muse, mutect2, varscan2
- EDNRA | c.516C>T p.T172= | Silent (SNP) | VAF 56/126 reads (44%) | catalogued as rs753966078, COSV100163232; called by muse, mutect2, varscan2
- ENPP2 | c.2430G>A p.E810= (on ENST00000075322 / NM_001040092.3; = p.E862= on NM_006209.5) | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as COSV99307619; called by muse, mutect2, varscan2
- FBN1 | c.3561T>C p.H1187= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100354109; called by muse, mutect2
- GABRB1 | c.415C>A p.R139= | Silent (SNP) | VAF 69/133 reads (52%) | catalogued as COSV99780393; called by muse, mutect2, varscan2
- GOLGB1 | c.6999A>G p.E2333= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV61467978; called by muse, mutect2, varscan2
- GRM1 | c.2055C>T p.I685= | Silent (SNP) | VAF 153/211 reads (73%) | catalogued as COSV51128054; called by muse, mutect2, varscan2
- GRTP1 | c.249G>C p.G83= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100390958; called by muse, mutect2, varscan2
- HEY1 | c.33G>A p.S11= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs749975418, COSV100559168; called by muse, varscan2
- HIVEP2 | c.5202G>A p.A1734= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs200547940; called by muse, mutect2, varscan2
- HOXA6 | c.339C>T p.P113= | Silent (SNP) | VAF 63/97 reads (65%) | catalogued as rs776052179, COSV99762112; called by muse, mutect2, varscan2
- ITGA7 | c.2925C>T p.S975= (on ENST00000555728; = p.S931= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV99144404; called by muse, mutect2, varscan2
- ITGA7 | c.462G>A p.L154= | Silent (SNP) | VAF 74/134 reads (55%) | catalogued as rs1366755662, COSV99144412; called by muse, mutect2, varscan2
- KCNJ10 | c.771T>C p.H257= | Silent (SNP) | VAF 34/136 reads (25%) | catalogued as rs775848365, COSV63634357; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KIF17 | c.186C>T p.H62= | Silent (SNP) | VAF 83/102 reads (81%) | catalogued as COSV99928606; called by muse, mutect2, varscan2
- KIF20B | c.4140A>T p.T1380= (on ENST00000371728 / NM_001284259.2; = p.T1340= on NM_016195.4) | Silent (SNP) | VAF 80/113 reads (71%) | catalogued as COSV99589569; called by muse, mutect2, varscan2
- L1CAM | c.2370C>T p.A790= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs145717130, COSV100648892; ClinVar: likely benign; called by muse, mutect2, varscan2
- LMO7 | c.3744C>T p.A1248= (on ENST00000357063; = p.A929= on NM_005358.5) | Silent (SNP) | VAF 46/58 reads (79%) | catalogued as rs762082667, COSV58533727; called by muse, mutect2, varscan2
- LTBP4 | c.4479C>T p.G1493= (on ENST00000308370 / NM_001042544.1; = p.G1456= on NM_003573.2) | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as COSV99180576; called by muse, mutect2, varscan2
- MAGEL2 | c.2448A>T p.S816= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV100045762; called by muse, mutect2, varscan2
- MAST4 | c.6642T>A p.S2214= (on ENST00000403625 / NM_001164664.2; = p.S2025= on NM_015183.3) | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as COSV99843050; called by muse, mutect2, varscan2
- MYH13 | c.3210T>C p.I1070= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99352524; called by muse, varscan2
- MYO9B | c.6255G>C p.P2085= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as COSV99812378; called by muse, varscan2
- NEB | c.15942C>T p.S5314= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99415792; called by muse, mutect2, varscan2
- NLRP11 | c.543G>C p.S181= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs373915016; called by muse, mutect2, varscan2
- NOD2 | c.1671C>T p.G557= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as rs35422070; called by muse, varscan2
- NPAP1 | c.1248C>T p.Y416= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV100274844; called by muse, mutect2, varscan2
- NUDCD3 | c.558C>T p.V186= | Silent (SNP) | VAF 46/60 reads (77%) | catalogued as rs1258640028, COSV100819279; called by muse, mutect2, varscan2
- OR2V2 | c.915G>T p.G305= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100080020; called by muse, mutect2, varscan2
- OR4M1 | c.81A>G p.L27= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV100270964; called by muse, mutect2, varscan2
- OR51B2 | c.190C>T p.L64= | Silent (SNP) | VAF 57/81 reads (70%) | catalogued as COSV100173288; called by muse, mutect2, varscan2
- OR9Q1 | c.75C>G p.L25= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as COSV100109436, COSV100110193; called by muse, mutect2, varscan2
- OSM | c.525G>T p.P175= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV53160686, COSV53162182, COSV99304064; called by muse, mutect2, varscan2
- PACSIN2 | c.162G>T p.A54= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV54321316, COSV99605943; called by muse, mutect2, varscan2
- PAX1 | c.495C>A p.I165= | Silent (SNP) | VAF 74/165 reads (45%) | catalogued as rs751100994, COSV101270219; called by muse, mutect2, varscan2
- PCDHA10 | c.1446C>T p.D482= | Silent (SNP) | VAF 84/214 reads (39%) | catalogued as COSV56541619; called by muse, varscan2
- PDZD2 | c.2109G>C p.A703= | Silent (SNP) | VAF 13/140 reads (9%) | catalogued as COSV99223911; called by muse, mutect2
- PLAAT3 | c.285G>A p.R95= | Silent (SNP) | VAF 56/145 reads (39%) | catalogued as COSV100071674; called by muse, mutect2, varscan2
- POLN | c.1566G>A p.L522= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV101242478; called by muse, mutect2, varscan2
- PPEF2 | c.1110C>T p.S370= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as rs776220516, COSV99714168; called by muse, mutect2, varscan2
- PTCH2 | c.2911C>T p.L971= | Silent (SNP) | VAF 30/50 reads (60%) | catalogued as COSV100941938; called by muse, mutect2, varscan2
- PTPRF | c.3534G>T p.R1178= | Silent (SNP) | VAF 123/156 reads (79%) | catalogued as COSV100740668; called by muse, mutect2, varscan2
- REC8 | c.177C>A p.G59= | Silent (SNP) | VAF 62/92 reads (67%) | catalogued as COSV100268885; called by muse, mutect2, varscan2
- RPL10 | c.15C>T p.P5= | Silent (SNP) | VAF 358/437 reads (82%) | catalogued as rs1557184932, COSV99185824; called by muse, mutect2, varscan2
- RSPO3 | c.228T>C p.C76= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs373891496; called by muse, mutect2, varscan2
- SACS | c.6844T>C p.L2282= | Silent (SNP) | VAF 42/51 reads (82%) | catalogued as COSV101207214; called by muse, mutect2, varscan2
- SHPK | c.639C>T p.N213= | Silent (SNP) | VAF 28/181 reads (15%) | catalogued as rs117712271; called by muse, mutect2, varscan2
- SLC25A16 | c.540A>G p.A180= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as COSV99770016; called by muse, mutect2, varscan2
- SLC25A39 | c.876T>G p.A292= (on ENST00000377095 / NM_001143780.3; = p.A284= on NM_016016.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV99835128; called by muse, mutect2, varscan2
- SLC2A5 | c.753G>C p.R251= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as COSV101072621; called by muse, mutect2, varscan2
- SMYD2 | c.1260T>C p.H420= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV100873123; called by muse, mutect2
- SPAG17 | c.147C>T p.L49= | Silent (SNP) | VAF 49/69 reads (71%) | catalogued as rs763779341, COSV100308139; called by muse, mutect2, varscan2
- SPATA31A3 | c.3498C>T p.N1166= | Silent (SNP) | VAF 60/99 reads (61%) | called by muse, mutect2, varscan2
- SYCP1 | c.135T>C p.D45= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV101050781; called by muse, mutect2, varscan2
- TEX101 | c.33C>A p.I11= (on ENST00000598265 / NM_001130011.3; = p.I29= on NM_031451.4) | Silent (SNP) | VAF 72/209 reads (34%) | catalogued as COSV99494704, COSV99494882; called by muse, mutect2, varscan2
- TGM6 | c.264A>T p.A88= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as COSV99171690; called by muse, mutect2, varscan2
- TM4SF18 | c.426T>C p.S142= | Silent (SNP) | VAF 43/70 reads (61%) | catalogued as rs374280069; called by muse, mutect2, varscan2
- TMTC1 | c.1212G>T p.V404= (on ENST00000539277 / NM_001193451.2; = p.V296= on NM_175861.3) | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV99758881; called by muse, mutect2, varscan2
- TP53TG5 | c.357G>A p.G119= | Silent (SNP) | VAF 122/215 reads (57%) | catalogued as rs1195329154, COSV101022308; called by muse, mutect2, varscan2
- TPO | c.565C>A p.R189= | Silent (SNP) | VAF 45/56 reads (80%) | catalogued as COSV100219881; called by muse, mutect2, varscan2
- TSC1 | c.1848C>T p.A616= | Silent (SNP) | VAF 28/37 reads (76%) | catalogued as rs752286096, COSV100051249; ClinVar: benign; called by muse, mutect2, varscan2
- TTN | c.34968T>A p.V11656= (on ENST00000591111; = p.V10729= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/60 reads (73%) | catalogued as COSV60132418; called by muse, mutect2, varscan2
- TTN | c.23163C>T p.N7721= (on ENST00000591111; = p.N6794= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/124 reads (73%) | catalogued as rs199576800, COSV60025026; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- UNC45B | c.1167C>A p.P389= | Silent (SNP) | VAF 30/38 reads (79%) | catalogued as COSV99268272; called by muse, mutect2, varscan2
- WDR44 | c.1842A>G p.S614= | Silent (SNP) | VAF 36/51 reads (71%) | catalogued as COSV99561228; called by muse, mutect2, varscan2
- XPOT | c.2616C>T p.H872= | Silent (SNP) | VAF 8/217 reads (4%) | called by muse, mutect2
- ZDHHC19 | c.186T>G p.P62= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99579415; called by muse, mutect2, varscan2
- ZNF302 | c.708A>G p.S236= (on ENST00000627982; = p.S157= on NM_018443.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV101416435; called by muse, mutect2, varscan2
- CR1 | c.487+12171A>G | Intron (SNP) | VAF 82/277 reads (30%) | catalogued as COSV100887412; called by muse, mutect2, varscan2
- CTSL3P | n.563G>T | RNA (SNP) | VAF 56/88 reads (64%) | called by muse, mutect2, varscan2
- LINC00482 | n.857C>T | RNA (SNP) | VAF 18/27 reads (67%) | catalogued as rs372289688; called by muse, mutect2, varscan2
- SCFD2 | c.*2C>T | 3'UTR (SNP) | VAF 22/82 reads (27%) | catalogued as COSV101189288; called by muse, mutect2, varscan2
- TTN | c.10303+2236C>T | Intron (SNP) | VAF 23/34 reads (68%) | catalogued as COSV100596897; called by muse, mutect2, varscan2
